Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A41L, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A41L-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED]
NAME: [REDACTED]
BIRTHDATE: [REDACTED]

PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]

SEX: [REDACTED]
ADM DATE: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

REQ DOC: [REDACTED]

PROCEDURE: SPHS

VERIFIED BY: [REDACTED]

Source of Specimen: Total thyroid.
year-old with history of papillary carcinoma newly diagnosed.
Operative Procedure: Total thyroidectomy. Total thyroid level 6 nodes thyroid
area and neck.

PROCEDURE: SPGD

VERIFIED BY: [REDACTED]

1. "Total thyroid" Received in a small container is a 14.3 gram total
thyroidectomy including a right lobe that is 4.5 x 1.5 x 1.6 cm and a left
lobe that is 4.7 x 1.9 x 0.9 cm. The right lobe is inked green the left is
inked blue and the isthmus is inked yellow. Serially sectioned to reveal a 2 x
1.5 x 3.2 cm pink-white, circumscribed tumor in the right lobe that comes to
within 1.3 cm of the isthmus and abuts the inked surface, parenchyma is
red-brown, grossly unremarkable.
1A-D. Entire nodule.
1E. Remainder of right lobe and isthmus.
1F-H. Left lobe including isthmus.
2. "Level VI nodes thyroid areas of neck" Received in a small container is a
3.5 x 2.5 x 0.6 cm aggregate of fibroadipose tissue, including possible lymph
nodes. One cassette.

PROCEDURE: SPMI

VERIFIED BY: [REDACTED]

PAPILLARY THYROID CARCINOMA

Size of primary tumor: 3.2 x 2 x 1.5 cm.

Location: Right lobe.

Capsular Invasion: No.

Vascular Invasion: No.

Margins: Negative.

Extrathyroidal extension: N.A.

Lymph node metastases: No.

Extranodal extension: N.A.

1CD003

Carcinoma, papillary, follicular
variant

Site: thyroid, NOS
C73.9

8340/3

7-23-12
RD

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED]
NAME: [REDACTED]
BIRTHDATE: [REDACTED]

PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]

PAGE #: 3
SEX: [REDACTED]
ADM DATE: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

REQ DOC: [REDACTED]

PROCEDURE: SPDX

VERIFIED BY: [REDACTED]

1. Thyroid, total thyroidectomy: Papillary carcinoma of the thyroid, follicular type, arising in the right lobe (greatest dimension 3.2 cm). All surgical margins negative. Left lobe shows nodular hyperplasia. *Per TSS, follicular variant is > 99%. JW*

2. Soft tissue in the region of the thyroid ("level VI nodes"), excision: Three histologically unremarkable lymph nodes and a portion of hyperplastic thymus gland. No evidence of metastatic disease.

[REDACTED]

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file fb06669a-624f-4bdc-99c9-20d1ac678eee (TCGA-KS-A41L.982CB386-A34A-4610-B9A8-9A6A43F84D87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).